Gene-level copy-number profile of tumor specimen TCGA-IE-A4EJ-01A from TCGA case TCGA-IE-A4EJ, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Giant cell sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 84.5 years (30,858 days).
Specimen TCGA-IE-A4EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.c8409e1e-e721-4d28-ab10-cf6a7a529e00.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IE-A4EJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e06c11db-bb1c-449c-95b1-b6465e3b7f84

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 3,995; copy number 2: 24,527; copy number 3: 12,896; copy number 4: 11,352; copy number 5: 4,138; copy number 6: 1,222; copy number 7: 397; copy number 8: 815; copy number 9: 132; copy number 10: 146; copy number 12: 151; copy number 16: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IE-A4EJ-01A-11D-A24M-01): tumor purity 0.55, ploidy 2.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:60,486,819–65,576,345, 36 genes (within-gene range 0–2): AC009081.1, GNPATP, AC009169.1, RPS27AP16, AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1, AC040174.1, AC040174.2, UBE2FP2, AC138305.1, RPS15AP34, AC138305.2, AC138305.3, AC018846.1, LINC02165, AC092337.1, AC093536.2, AC012322.1, AC093536.1, AC092131.1, PPIAP48, AC009101.1, CDH11, AC010533.1, LINC02126, AC009055.2, AC009055.1, LINC00922.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,475 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–4,019,508, 208 genes, copy number 5 (broad region; genes not listed).
- chr3:84,638,405–90,261,708, 47 genes, copy number 5–7: LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr4:49,096–33,693,993, 519 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr4:52,680,609–54,859,241, 40 genes, copy number 9: AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358.
- chr5:58,198–35,429,277, 539 genes, copy number 5–10 (broad region; genes not listed).
- chr5:66,085,405–83,582,303, 343 genes, copy number 5–6 (broad region; genes not listed).
- chr6:90,513,573–90,587,072, 1 gene, copy number 5: MAP3K7.
- chr6:94,446,740–118,317,676, 311 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:122,211,648–125,302,078, 28 genes, copy number 5: RNU1-18P, HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1.
- chr7:2,728,105–22,773,993, 277 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:50,388,489–50,400,097, 1 gene, copy number 8: AC124014.1.
- chr7:52,493,152–53,811,952, 13 genes, copy number 10 (within-gene range 3–10): AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9.
- chr7:54,721,724–55,862,755, 31 genes, copy number 8 (within-gene range 3–8): AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr7:56,805,336–57,837,046, 70 genes, copy number 7 (broad region; genes not listed).
- chr7:65,463,071–65,463,438, 1 gene, copy number 6: AC114501.3.
- chr8:12,696,307–43,674,591, 595 genes, copy number 5 (broad region; genes not listed).
- chr11:28,679,183–39,161,967, 148 genes, copy number 6 (broad region; genes not listed).
- chr11:43,120,762–46,321,409, 81 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:72,087,266–72,670,758, 1 gene, copy number 5 (within-gene range 3–5): TRHDE.
- chr12:72,431,722–123,366,113, 941 genes, copy number 5 (broad region; genes not listed).
- chr14:36,320,753–42,268,586, 70 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr15:48,645,951–101,933,350, 1,329 genes, copy number 5–6 (broad region; genes not listed).
- chr19:19,708,965–24,163,425, 209 genes, copy number 5 (broad region; genes not listed).
- chr20:39,655,325–64,313,132, 601 genes, copy number 6–9 (broad region; genes not listed).
- chr21:14,676,698–19,134,423, 71 genes, copy number 6–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,995. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
